Gene-level copy-number profile of tumor specimen TCGA-33-4589-01A from TCGA case TCGA-33-4589, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.3 years (22,754 days).
Specimen TCGA-33-4589-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.193f7c29-051b-4739-9dc9-d471b5b045d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-4589-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df0d991d-1158-4be7-9023-d78cdd826c8a

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 269; copy number 3: 6,618; copy number 4: 13,742; copy number 5: 18,924; copy number 6: 10,379; copy number 7: 2,461; copy number 8: 4,334; copy number 9: 2,536; copy number 10: 224; copy number 11: 27; copy number 13: 21; copy number 15: 55; copy number 16: 8; copy number 18: 143; copy number 19: 50; copy number 23: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-4589-01A-01D-1439-01): tumor purity 0.2, ploidy 4.7, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 325 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:46,670,444–49,360,420, 35 genes, copy number 11–16 (within-gene range 8–16): AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42.
- chr7:53,787,167–56,848,800, 92 genes, copy number 13–23 (within-gene range 7–23) (broad region; genes not listed).
- chr7:86,216,785–93,361,123, 96 genes, copy number 15–18 (broad region; genes not listed).
- chr7:93,482,760–93,484,019, 2 genes, copy number 18: MIR653, MIR489.
- chr7:101,127,104–105,115,019, 100 genes, copy number 18 (within-gene range 3–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
